Somatic mutation profile of tumor specimen TCGA-DD-AADK-01A (aliquot TCGA-DD-AADK-01A-11D-A40R-10) from TCGA case TCGA-DD-AADK, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 68.6 years (25,046 days).
Specimen TCGA-DD-AADK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e01e170-4e12-44f4-9d96-7cbf4fd477ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADK-10A (Blood Derived Normal), aliquot TCGA-DD-AADK-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52e841bd-d855-4f96-979c-58ceddedd986

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 12, Frame Shift Del 3, Nonsense Mutation 3, Intron 2, RNA 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MVK | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs104895352, CM055448, COSV57332211; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- SETD2 | c.4715+1G>A p.X1572_splice | Splice Site (SNP) | VAF 22/80 reads (28%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, mutect2, varscan2
- ADGRG4 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs867387521, COSV99794161; called by muse, mutect2, varscan2
- ADGRV1 | c.15523G>A p.V5175M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs535921202, COSV101315368; called by muse, mutect2, varscan2
- AGR3 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100123827; called by muse, mutect2, varscan2
- BBOX1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54190455; called by muse, mutect2, varscan2
- C7orf25 | c.1004A>C p.N335T | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV100623584; called by muse, mutect2, varscan2
- COL11A1 | c.1790A>G p.K597R | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV100614698; called by muse, mutect2, varscan2
- CRLF3 | c.702C>G p.F234L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); catalogued as COSV100158233; called by muse, mutect2
- CRTC2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV100338763; called by muse, mutect2, varscan2
- DDX18 | c.651G>T p.R217S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV99604241; called by muse, mutect2, varscan2
- DYRK3 | c.908A>T p.K303M | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100895570; called by muse, mutect2, varscan2
- EPB41L3 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 30/156 reads (19%) | catalogued as COSV100548029; called by muse, mutect2, varscan2
- ERCC4 | c.2464C>T p.Q822* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100318591; called by muse, mutect2, varscan2
- ESYT1 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99919596; called by muse, mutect2, varscan2
- GLI3 | c.704C>G p.A235G | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV67894513; called by muse, mutect2, varscan2
- GRIPAP1 | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV100904161; called by muse, mutect2, varscan2
- H1-2 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59190705, COSV59193232; called by muse, mutect2, varscan2
- IGSF1 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 25/467 reads (5%) | catalogued as COSV100811768, COSV63836256; called by muse, mutect2
- KDM7A | c.2672T>G p.L891R | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99133863; called by muse, mutect2, varscan2
- KIAA0586 | c.2569G>A p.E857K (on ENST00000619416 / NM_001244190.2; = p.E796K on NM_014749.5) | Missense Mutation (SNP) | VAF 59/371 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99707348; called by muse, mutect2, varscan2
- KIAA1841 | c.1594A>G p.T532A | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV99693208; called by muse, mutect2, varscan2
- MROH5 | c.3443T>A p.L1148Q | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100267024; called by muse, mutect2, varscan2
- NLRP6 | c.1574G>A p.G525D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.476); catalogued as rs1436139839, COSV100380909; called by muse, mutect2, varscan2
- NRSN2 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101206779; called by muse, mutect2, varscan2
- PLA2G4A | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs28395828; called by muse, mutect2, varscan2
- PPARA | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99415044; called by muse, mutect2, varscan2
- PROM2 | c.1039A>G p.M347V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1261958274, COSV100468567; called by muse, mutect2, varscan2
- RHOB | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV55355290, COSV55357347; called by mutect2, varscan2
- RNF114 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1462212625, COSV54870159, COSV99724628; called by muse, mutect2
- RNF213 | c.1771T>C p.W591R | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.99); catalogued as COSV100172899; called by muse, mutect2
- RPRD1A | c.550C>T p.H184Y | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV100036057, COSV59823524; called by muse, mutect2, varscan2
- RUBCN | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV99583002; called by muse, mutect2, varscan2
- SEMA6C | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs755889939, COSV100501033; called by muse, mutect2, varscan2
- SHMT2 | c.1081A>G p.M361V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV100196935; called by muse, mutect2, varscan2
- STYXL2 | c.2789A>G p.E930G | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV99608460; called by muse, mutect2
- SUPT5H | c.3070A>G p.S1024G | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100067690; called by muse, mutect2, varscan2
- SYCP2 | c.1951A>G p.T651A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1391811122, COSV100697908; called by muse, mutect2, varscan2
- TRO | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV51509354, COSV99435635; called by muse, mutect2, varscan2
- TTBK2 | c.3390T>A p.S1130R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99141050; called by muse, mutect2, varscan2
- UBE3C | c.2777A>G p.Y926C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100779649; called by muse, mutect2, varscan2
- UCP2 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100134935; called by muse, mutect2, varscan2
- VANGL1 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100048758; called by muse, mutect2, varscan2
- YY2 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV100810656, COSV63412459; called by muse, mutect2, varscan2
- ZFR | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99415257; called by muse, mutect2
- ZNF687 | c.2932T>A p.Y978N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99649228; called by muse, mutect2, varscan2
- ADCY1 | c.242_267del p.L81Pfs*147 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- DCDC2 | c.739_756delinsCTCC p.S247Lfs*5 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by pindel, varscan2*
- FMO3 | c.1318_1320del p.F440del | In Frame Del (DEL) | VAF 13/135 reads (10%) | called by mutect2, pindel, varscan2
- PPP1R12B | c.231del p.L78Wfs*15 | Frame Shift Del (DEL) | VAF 21/147 reads (14%) | called by mutect2, pindel, varscan2
- TXLNG | c.189dup p.L64Sfs*13 | Frame Shift Ins (INS) | VAF 81/469 reads (17%) | called by mutect2, pindel, varscan2
- ABCG4 | c.1923G>T p.R641= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100266447; called by muse, mutect2, varscan2
- CAPN13 | c.480A>G p.Q160= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs1428673264, COSV99699630; called by muse, mutect2, varscan2
- CNTN2 | c.195C>T p.A65= | Silent (SNP) | VAF 80/163 reads (49%) | catalogued as rs750251767, COSV100084594; called by muse, mutect2, varscan2
- FOXN2 | c.1251A>C p.L417= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100488920; called by muse, mutect2, varscan2
- GALNT6 | c.72C>T p.L24= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs765711039, COSV100695271; called by muse, mutect2, varscan2
- HNRNPD | c.114G>A p.A38= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1412331228, COSV58314478; called by muse, mutect2
- OR9K2 | c.999T>C p.I333= (on ENST00000305377; = p.I311= on NM_001005243.1) | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100543725; called by muse, mutect2, varscan2
- PREX2 | c.2835T>A p.V945= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV99904532; called by muse, mutect2
- RIMKLA | c.183G>A p.K61= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV101343441; called by muse, mutect2, varscan2
- TRBV20-1 | c.255T>C p.H85= | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- UBR5 | c.7092T>C p.F2364= | Silent (SNP) | VAF 6/160 reads (4%) | catalogued as COSV99639006; called by muse, mutect2
- ZNF345 | c.222A>G p.V74= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs754906884, COSV100080113; called by muse, mutect2, varscan2
- CR1 | c.487+15236C>A | Intron (SNP) | VAF 37/285 reads (13%) | catalogued as COSV100887342; called by muse, mutect2, varscan2
- MGAT4B | c.98-28del | Intron (DEL) | VAF 43/145 reads (30%) | called by mutect2, pindel, varscan2
- MIR498 | n.47G>T | RNA (SNP) | VAF 6/37 reads (16%) | catalogued as rs1477833978; called by muse, mutect2, varscan2
- SSX9P | n.126G>T | RNA (SNP) | VAF 110/623 reads (18%) | called by muse, mutect2, varscan2
